Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3AS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3AS-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED] Collected: [REDACTED]
DOB: [REDACTED] Visit #: [REDACTED] Received: [REDACTED]
Gender: [REDACTED] Location: [REDACTED] Reported: [REDACTED]
HCN: [REDACTED] Facility: [REDACTED]
Ordering MD: [REDACTED]
Copy To: [REDACTED]

Specimen(s) Received

1. Soft-Tissue: Left Fallopian Tube and Ovary
2. Soft-Tissue: Right Fallopian Tube and Ovary
3. Uterus: Uterus and cervix

Diagnosis

1. Left Fallopian Tube and Ovary:
Ovary- Surface adhesions, negative for tumor
Fallopian tube- Negative for tumor

2. Right Fallopian Tube and Ovary:
Ovary- Surface adhesions, negative for tumor
Fallopian tube- Negative for tumor

3. Uterus and cervix:
Endometrial adenocarcinoma, endometrioid type, FIGO grade 3/3 with:
- Invasion into inner half of myometrium
- Positive for involvement of cervix (glandular)
- No diagnostic evidence of lymphovascular space invasion
- Background endometrium: atrophic

Please see synoptic report

Synoptic Data

----- MACROSCOPIC -----
Specimen Type: Total Hysterectomy
Tumor Site: Posterior endometrium
Tumor Size: Greatest dimension: 3.3 cm
Additional dimensions: 2.9x1.8 cm
Other Organs Present: Right ovary
Left ovary
Right fallopian tube
Left fallopian tube

----- MICROSCOPIC -----
Histologic Type: Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade: G3: More than 50% nonsquamous solid growth
Myometrial Invasion: Invasion Present

ICD-0-3
adenocarcinoma, endometrioid, NOS

Site: endometrium C54.1

8380/B

hw
11/13/11

[page 2 of 3]
Surgical Pathology Consultation Report

Cervix Involvement:	Less than 50% myometrial invasion
LUS Involvement:	Glandular involvement of endocervix
Venous/Lymphatic Invasion:	No
Nodal Involvement:	Absent
Margins:	No nodes submitted
Primary Tumor (pT):	Uninvolved by invasive carcinoma
Regional Lymph Nodes (pN):	Tumor limited to the glandular epithelium of the endocervix. There is no evidence of connective tissue stromal invasion.
Distant Metastasis (pM):	pNX: Regional lymph nodes cannot be assessed
Additional Pathologic Findings:	Number of regional lymph nodes examined: 0
NeoAdjuvant Treatment:	Number of regional lymph nodes involved: 0
Collaborative Staging Extension:	pMX: Distant metastasis cannot be assessed
	None identified
	Unknown
	Not applicable

Electronically verified by:
MD

Gross Description

1. The specimen labeled with the patient's name and as "Soft-Tissue: Left fallopian tube and ovary". It consists of a left ovary with attached fallopian tube/parovarian tissue, weighing 4.7 g (fresh). The left ovary measures 2.6 x 1.2 x 0.7 cm. The surface of the ovary appears pale-tan and smooth. Cross sections show corpus albicans. The attached fallopian tube measures 2.5 cm in length x 0.5 cm in diameter. The surface of the fallopian tube appears pink-tan and smooth. Cross sections appear pale-tan and grossly unremarkable. One section from the ovary/fallopian tube has been taken for tissue banking. Representative sections are submitted as follows:

1A section of left ovary/fallopian tube, previously submitted by

1B left fimbria, longitudinally bisected

1C remainder of left fallopian tube, EIT

1D sections of left ovary, adjacent to tissue banking

1E-1G remainder of left ovary, EIT

2. The specimen labeled with the patient's name and as "Soft-Tissue: Right fallopian tube and ovary". It consists of a right ovary with attached fallopian tube/parovarian tissue, weighing 6.0 g (fresh). The right ovary measures 2.2 x 1.6 x 0.9 cm. The surface of the ovary appears pale-tan and smooth. Cross sections show corpus albicans. The attached fallopian tube measures 2.4 cm in length x 0.6 cm in diameter. The surface of the fallopian tube appears pink-tan and smooth. Cross sections appear pale-tan and grossly unremarkable. The adjacent parovarian tissue shows multiple cysts, ranging from 0.1 up to 0.3 cm in diameter (all filled with white milky fluid). One section from the ovary/fallopian tube has been taken for tissue banking. Representative sections are submitted as follows:

2A section of right ovary/fallopian tube, previously submitted by

2B-2C right fimbria, longitudinally quadrisectioned

2D remainder of right fallopian tube,

2E sections of right ovary, adjacent to tissue banking

2F-2H remainder of right ovary,

3. The specimen, labeled with the patient's name and as "Uterus: Uterus and cervix". The specimen is received fresh and subsequently placed in 10% buffered formalin. It consists of a uterus with attached cervix, weighing 61.5 g (fresh). The body of the uterus is uniform and measures 6.0 cm SI x 4.2 cm ML x 2.5 cm AP. The serosal surface is pink-tan and smooth. The cervix has a maximum diameter of 2.6 cm. The cervical Os measures 1.0 cm in maximum diameter and has an oval shape. The uterus is bivalved. Both endo/myometrial layers are not of uniform thickness. Within the endometrial cavity, a well-circumscribed tumor is identified measuring 2.9 cm SI x 3.3 cm ML x 1.8 cm AP. The cut surface of the tumor appears homogeneously white, solid and firm; showing gross invasion into the myometrium. The tumor is located: 1.1 cm from the anterior exocervix, 1.5 cm from the posterior exocervix and 0.6 cm from the closest serosal surface (anterior aspect). The cervical canal is patent and shows small amounts of mucoid material. The cervix reveals a few

[page 3 of 3]
Surgical Pathology Consultation Report

Nabothian cysts, the largest measuring 0.5 cm in diameter. All of the Nabothian cysts are filled with clear gelatinous material. Two sections of endometrial tumor have been taken for tissue banking. Representative sections are submitted as follows:

3A one section of endometrial tumor, previously submitted by research PA

3B-3C two full-thickness/transverse sections of endo/myometrium (including endometrial tumor), anterior aspect

3D-3E a full-length/full thickness section of endo/myometrium (including endometrial tumor), from endometrial cavity to exocervix, anterior aspect

3F-3G a full thickness/transverse section of endo/myometrium (including endometrial tumor), posterior aspect

3H-3I a full thickness/transverse section of endo/myometrium (including endometrial tumor), posterior aspect

3J-3K a full length/full thickness section of endo/myometrium (including endometrial tumor), from endometrial cavity to exocervix, posterior aspect

Source: NCI Genomic Data Commons file 76cb41ec-2492-40e6-8230-ba5093d502aa (TCGA-EO-A3AS.844799B1-4C96-473A-8ECB-71ACB080F95E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).